Somatic mutation profile of tumor specimen 0DQC23 from CCDI case PBCEWI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.8 years (293 days).
Specimen 0DQC23: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db2d938b-9c7f-4fa5-8a67-ce0bfa0dd6ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQC27 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c93eff0e-ed64-4c6d-af0e-db6a0b07b77c

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Missense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1384C>A p.P462T (on ENST00000288602 / NM_001374244.1; = p.P422T on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 719/1936 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV56238174; called by muse, mutect2, varscan2
- ANKRD30A | c.1836C>T p.C612= (on ENST00000611781; = p.C556= on NM_052997.2) | Silent (SNP) | VAF 243/770 reads (32%) | catalogued as rs564834347, COSV64609205; called by muse, mutect2, varscan2
- SPIN4 | c.204C>T p.S68= | Silent (SNP) | VAF 22/572 reads (4%) | called by muse, mutect2
- FAM236D | c.*32G>A | 3'UTR (SNP) | VAF 122/385 reads (32%) | called by muse, mutect2, varscan2
